CPTAC case C3N-02784 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/aa7502a9-5ffe-48c1-a1a8-3b07e83f78d7

Demographics
Sex at birth: male; Race: asian; Year of birth: 1980; Vital status: Dead; Days to death: 391 days (1.1 years); Year of death: 2018; Cause of death: Cancer Related; Country of birth: China.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Age at diagnosis: 37.1 years (13,569 days); Year of diagnosis: 2017; Last known disease status: With tumor; Days to last known disease status: 391 days (1.1 years); Progression or recurrence: yes; Days to recurrence: 190 days; Days to last follow up: 391 days (1.1 years).
   Pathology details: Greatest tumor dimension: 5 cm.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (1 entry)
- Days to follow up: 391 days (1.1 years); Disease response: With Tumor; Progression or recurrence: Yes; Days to recurrence: 555 days (1.5 years); Karnofsky performance status: 0; ECOG performance status: 5.

Other clinical attributes
- Weight: 90 kg; Height: 175 cm; BMI: 29.39.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 20; Cigarettes per day: 20; Tobacco smoking onset year: 1997; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker; Exposure duration years: 25.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-02784-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -5 days; Initial weight: 125 mg; Time between excision and freezing: 10 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-02784-21: Section location: Left Hemisphere and Frontal Lobe and Temporal Lobe; Percent tumor nuclei: 70; Percent necrosis: 20.
- Sample C3N-02784-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -5 days; Initial weight: 125 mg; Time between excision and freezing: 10 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-02784-23: Section location: Left Hemisphere and Frontal Lobe and Temporal Lobe; Percent tumor nuclei: 80; Percent necrosis: 20.
- Sample C3N-02784-71: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -6 days; Method of sample procurement: Blood Draw.
